Somatic mutation profile of tumor specimen e3ebe010-cd31-4b5d-8fcb-b7103b (aliquot e3ebe010-cd31-4b5d-8fcb-b7103b_D6) from CPTAC case 04OV004, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IV.
Specimen e3ebe010-cd31-4b5d-8fcb-b7103b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4debd1f-11da-41bd-9514-1c36c54c37eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0a3efca2-3684-4fc6-a20d-af55ba (Blood Derived Normal), aliquot 0a3efca2-3684-4fc6-a20d-af55ba_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/912c72de-138a-4af7-92e6-b98c4cbd6d28

The open-access MAF lists 110 somatic variants for this specimen: 81 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 22, Splice Site 5, Frame Shift Del 5, Nonsense Mutation 3, RNA 2, Intron 2, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 212/307 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 143/329 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV64419308; called by muse, mutect2, varscan2
- ANK1 | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs369132742; called by muse, mutect2
- APLP1 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 76/108 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99697970; called by muse, mutect2, varscan2
- BCHE | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 83/550 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.795); catalogued as rs200817146, COSV52259925; called by muse, mutect2, varscan2
- BPI | c.1450G>A p.V484I (on ENST00000262865; = p.V480I on NM_001725.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); catalogued as rs779376699, COSV53404935; called by muse, mutect2, varscan2
- CHMP4B | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 577/1031 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1240773481, COSV54135612; called by muse, mutect2, varscan2
- CSMD3 | c.7792C>T p.R2598* (on ENST00000297405 / NM_001363185.1; = p.R2494* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 77/311 reads (25%) | catalogued as COSV52119954; called by muse, mutect2, varscan2
- CSNK2A2 | c.806A>G p.H269R | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs1251533091; called by muse, mutect2, varscan2
- DOCK2 | c.2192A>T p.E731V | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56998021; called by muse, mutect2, varscan2
- DOCK8 | c.2142G>T p.W714C | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66620703; called by mutect2, varscan2
- FAM86B1 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1367947071; called by mutect2, varscan2
- HOXD4 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as rs187203814, COSV100107029; called by muse, mutect2, varscan2
- HPCA | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 127/193 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV65102828; called by muse, mutect2, varscan2
- IGSF1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 160/430 reads (37%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as rs776279784, COSV100812348; called by muse, mutect2, varscan2
- JMJD8 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 99/148 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370082299; called by muse, mutect2, varscan2
- LTBP3 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 256/735 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1404951929, COSV100099464; called by muse, mutect2, varscan2
- NCOR2 | c.1819A>G p.M607V | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs775799345; called by muse, mutect2, varscan2
- PI4KA | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs765835463; called by muse, mutect2, varscan2
- PKD1L1 | c.6608A>G p.H2203R | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs1216088454; called by muse, mutect2, varscan2
- PLK5 | c.489C>T p.A163= | Splice Region (SNP) | VAF 58/145 reads (40%) | catalogued as rs530946143; called by muse, mutect2, varscan2
- POLR3B | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs750694928; called by muse, mutect2, varscan2
- PRSS16 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV57915622; called by muse, mutect2, varscan2
- RAB11A | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 118/155 reads (76%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1224127056; called by muse, mutect2, varscan2
- RASA2 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs753274678; called by muse, mutect2, varscan2
- RCE1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1287027409; called by muse, mutect2, varscan2
- RPS6KB2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 137/320 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs565413086; called by muse, mutect2
- SCARF2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 294/827 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335979332; called by muse, mutect2, varscan2
- SLC10A5 | c.656del p.G219Vfs*10 | Frame Shift Del (DEL) | VAF 28/63 reads (44%) | catalogued as rs753342009; called by mutect2, pindel, varscan2
- SNRNP200 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 254/630 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs368983658; called by muse, mutect2, varscan2
- STK11 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs775595174, COSV58820311, COSV58831059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TET3 | c.3203C>T p.A1068V | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101328011; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as rs201586158; called by muse, mutect2, varscan2
- ZNF142 | c.4361C>T p.T1454I (on ENST00000411696 / NM_001379660.1; = p.T1254I on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1368487726; called by muse, mutect2
- ADGB | c.4694A>C p.Q1565P | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- AKAP6 | c.718C>A p.L240I | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AL645922.1 | c.2011_2035del p.G671Wfs*62 | Frame Shift Del (DEL) | VAF 192/852 reads (23%) | called by pindel, varscan2
- B2M | c.205_224del p.V69Ffs*14 | Frame Shift Del (DEL) | VAF 145/255 reads (57%) | called by mutect2, pindel, varscan2
- BSN | c.8817C>A p.S2939R | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CEP250 | c.7066-1G>A p.X2356_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- CFAP99 | c.551T>A p.V184D | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CLEC4C | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CYREN | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 125/313 reads (40%) | called by muse, mutect2, varscan2
- DHRS7 | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.10555+2T>C p.X3519_splice | Splice Site (SNP) | VAF 122/338 reads (36%) | called by muse, mutect2, varscan2
- GABRB3 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 177/245 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HELZ | c.4795C>A p.P1599T | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSD17B10 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 297/777 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRF2BPL | c.2228C>G p.S743C | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITGA5 | c.1606G>T p.V536F | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNU1 | c.2436G>T p.L812F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- KRAS | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LHCGR | c.1282A>C p.N428H | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX9 | c.563A>C p.E188A | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- LRRC27 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDGA1 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTHFD2 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MVB12A | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCL | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NDUFAF7 | c.409-2_413del p.X137_splice | Splice Site (DEL) | VAF 28/232 reads (12%) | called by mutect2, pindel
- NLRP11 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 92/122 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NOC2L | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 85/128 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NR5A1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR52E2 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 107/165 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PIKFYVE | c.4720_4722del p.T1574del | In Frame Del (DEL) | VAF 115/336 reads (34%) | called by mutect2, pindel, varscan2
- RBM33 | c.2500C>G p.L834V | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- RBM47 | c.130dup p.Y44Lfs*64 | Frame Shift Ins (INS) | VAF 75/258 reads (29%) | called by mutect2, pindel, varscan2
- RFX2 | c.1248-1G>A p.X416_splice | Splice Site (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- RFX2 | c.1120A>G p.R374G | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SEMG1 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SF3A1 | c.1364T>G p.V455G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SH3PXD2A | c.1660G>T p.E554* (on ENST00000369774 / NM_001365079.1; = p.E526* on NM_014631.2) | Nonsense Mutation (SNP) | VAF 61/145 reads (42%) | called by muse, mutect2, varscan2
- SIN3A | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLAMF7 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC10A5 | c.1300_1304del p.R434Ffs*? | Frame Shift Del (DEL) | VAF 23/31 reads (74%) | called by mutect2, pindel, varscan2
- SLC10A5 | c.956_965del p.Y319Sfs*5 | Frame Shift Del (DEL) | VAF 38/72 reads (53%) | called by pindel, varscan2
- SLC5A5 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SRRT | c.2214G>C p.E738D | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TBC1D30 | c.2597A>T p.N866I (on ENST00000542120; = p.N703I on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TRIM9 | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 216/572 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TTLL11 | c.1636-13_1663del p.X546_splice | Splice Site (DEL) | VAF 27/135 reads (20%) | called by mutect2, pindel, varscan2
- ABCB7 | c.1777C>A p.R593= (on ENST00000373394 / NM_001271696.3; = p.R594= on NM_004299.6) | Silent (SNP) | VAF 108/290 reads (37%) | called by mutect2, varscan2
- ADCY2 | c.2622G>A p.K874= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- C16orf86 | c.183C>T p.G61= | Silent (SNP) | VAF 132/210 reads (63%) | called by muse, mutect2, varscan2
- C9 | c.702T>C p.N234= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV54674157; called by muse, mutect2, varscan2
- CPB1 | c.915G>A p.S305= | Silent (SNP) | VAF 98/424 reads (23%) | catalogued as rs762060736; called by muse, varscan2
- DACH2 | c.171C>T p.G57= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as rs1569282936; called by muse, mutect2
- GRIN2A | c.678C>A p.V226= | Silent (SNP) | VAF 223/350 reads (64%) | called by muse, mutect2, varscan2
- IL1RL2 | c.864C>G p.V288= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs942387865; called by muse, mutect2, varscan2
- ITGA11 | c.1012T>C p.L338= | Silent (SNP) | VAF 139/171 reads (81%) | called by muse, mutect2, varscan2
- KLHL4 | c.228A>T p.P76= | Silent (SNP) | VAF 117/309 reads (38%) | called by muse, mutect2, varscan2
- MUC5B | c.11046G>A p.T3682= | Silent (SNP) | VAF 148/261 reads (57%) | catalogued as rs769776719, COSV71594316; called by muse, mutect2, varscan2
- MYH14 | c.2799C>G p.R933= | Silent (SNP) | VAF 122/189 reads (65%) | called by muse, mutect2, varscan2
- NCOR2 | c.2916C>G p.A972= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV62304389; called by muse, varscan2
- POLA1 | c.345A>T p.A115= | Silent (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- PRPF6 | c.147A>T p.A49= | Silent (SNP) | VAF 161/390 reads (41%) | called by mutect2, varscan2
- PRTG | c.70C>T p.L24= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as rs762479325; called by muse, mutect2, varscan2
- RAE1 | c.999T>C p.A333= | Silent (SNP) | VAF 99/276 reads (36%) | called by muse, mutect2, varscan2
- RGL2 | c.99C>T p.G33= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs906668532; called by muse, mutect2, varscan2
- SLC7A4 | c.801T>G p.S267= | Silent (SNP) | VAF 124/298 reads (42%) | catalogued as rs370519763; called by mutect2, varscan2
- SYT13 | c.144G>T p.L48= | Silent (SNP) | VAF 119/299 reads (40%) | catalogued as rs1390872570, COSV99194682; called by muse, mutect2, varscan2
- TCN1 | c.1038T>C p.Y346= | Silent (SNP) | VAF 114/336 reads (34%) | called by muse, mutect2, varscan2
- ZNF518B | c.1071G>A p.Q357= | Silent (SNP) | VAF 85/322 reads (26%) | catalogued as COSV100456833; called by muse, mutect2, varscan2
- CYP4F8 | c.1314+13C>A | Intron (SNP) | VAF 64/269 reads (24%) | called by muse, mutect2, varscan2
- EXOG | n.1475A>T | RNA (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- FEZ1 | c.-314G>A | 5'UTR (SNP) | VAF 33/45 reads (73%) | catalogued as rs915386963; called by muse, mutect2, varscan2
- GUSBP1 | n.180-4579C>T | Intron (SNP) | VAF 132/1792 reads (7%) | catalogued as rs1426255708; called by muse, mutect2
- MIR124-2HG | n.364C>T | RNA (SNP) | VAF 42/58 reads (72%) | called by muse, mutect2, varscan2
- NKAIN3 | c.-71G>T | 5'UTR (SNP) | VAF 56/83 reads (67%) | called by muse, mutect2, varscan2
- Z97192.4 | chr22:49657437 G>T | 3'Flank (SNP) | VAF 53/75 reads (71%) | called by muse, mutect2, varscan2
